Somatic mutation profile of tumor specimen TARGET-50-PAKMSV-01A (aliquot TARGET-50-PAKMSV-01A-01D) from TARGET case TARGET-50-PAKMSV, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.4 years (1,968 days).
Specimen TARGET-50-PAKMSV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 389b8ffa-d928-4768-82b9-39a769aa644d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKMSV-10A (Blood Derived Normal), aliquot TARGET-50-PAKMSV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb1b87b0-1211-4afa-9083-9e92bdb64dba

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3D | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.04); catalogued as rs553533578, COSV53328348; called by muse, mutect2, varscan2
- CCNP | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.042); catalogued as rs1568501683; called by muse, mutect2
- F7 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60647653; called by muse, mutect2, varscan2
- FAM83B | c.2043G>T p.K681N | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV60926028; called by muse, mutect2, varscan2
- KATNIP | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200932520, COSV55190064; called by muse, mutect2, varscan2
- OR51I1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV66507307, COSV66507980; called by muse, mutect2
- ALG14 | c.612A>T p.E204D | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2
- PPFIBP1 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHDC7A | c.855C>A p.L285= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV68770775; called by muse, mutect2, varscan2
- TARBP1 | c.945T>C p.F315= | Silent (SNP) | VAF 62/325 reads (19%) | catalogued as COSV50200924; called by muse, mutect2, varscan2
- AP2A1 | c.2721+15G>T | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
